Gene-level copy-number profile of tumor specimen TCGA-5N-A9KM-01A from TCGA case TCGA-5N-A9KM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.7 years (26,906 days).
Specimen TCGA-5N-A9KM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a46a4a22-97b5-4e41-bf03-6de3c299e5be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5N-A9KM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/023b72ee-cb5b-4c82-8f8e-bc6b08f09fed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 54; copy number 2: 5,941; copy number 3: 2,651; copy number 4: 36,976; copy number 5: 10,884; copy number 6: 3,156; copy number 8: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5N-A9KM-01A-11D-A42D-01): tumor purity 0.72, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:17,157,162–18,444,817, 10 genes (within-gene range 0–5): TBC1D5, AC090960.1, AC140076.1, RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3, AC132807.1, AC132807.2.
- chr5:178,204,533–179,456,095, 35 genes: HNRNPAB, PHYKPL, COL23A1, AC136601.2, AC136601.1, RN7SL646P, AC008659.1, CLK4, RN7SKP70, AC113348.3, AC113348.1, AC113348.2, ZNF354A, AACSP1, AC126915.2, AC126915.1, AC126915.3, ZNF354B, RNU1-39P, ZFP2, AC104117.1, PIGFP1, AC104117.5, ZNF454, AC104117.3, GRM6, AC104117.4, ZNF879, ZNF354C, AC104117.2, ADAMTS2, AC109479.3, AC109479.1, AC109479.2, AC136628.1.
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:120,720,673–121,370,304, 17 genes (within-gene range 0–2): AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19, TRAF1, C5, CNTRL, RAB14, RN7SL181P, GSN, AL513122.1, AL513122.2, GSN-AS1, STOM.
- chr15:57,953,424–58,497,866, 1 gene (within-gene range 0–2): ALDH1A2.
- chr15:58,138,169–59,372,871, 41 genes (within-gene range 0–1): AQP9, MTCO3P23, MTND3P12, AC066616.2, MTND5P32, MTCYBP23, AC066616.1, LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2, AC018904.1, ADAM10, HMGB1P51, AC091046.1, HSP90AB4P, RN7SKP95, AC091046.2, AC090515.6, AC090515.3, SNORD3P1, AC090515.2, MINDY2, AC090515.5, AC090515.4, ZNF444P1, RNF111, AC090515.1, SLTM, AC025918.1, AC025918.2, AC092757.1, CCNB2, AC092757.3, AC092757.2, MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1.
- chr15:60,073,554–60,479,160, 7 genes: AC009654.1, AC037433.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
